Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GJ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GJ-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

History: Melanoma - WLE right calf 1.1mm, Clark level 4. - biopsy (RO lower leg melanoma, 1.1mm thick. Lump right groin 3/2010. FNA (+) melanoma. Staple (12 o'clock). 3 o'clock - blue. 9 o'clock - black.

MACROSCOPIC DESCRIPTION

(Dr

"RIGHT GROIN CONTENTS STAPLED UPPER". An ellipse of skin 165 x 25mm with attached fibrofatty tissue 180 x 70 x 60mm. 3mm deep to the skin, 5mm from the 9 o'clock margin, 10mm from the 3 o'clock margin and 20mm from the deep margin. There are two staples marking the upper margin taken to be 12 o'clock. The 3 o'clock margin has previously been inked blue, the 9 o'clock margin black. A deep lymph node 25mm in maximum dimension has been previously sampled for tumour bank. Towards the 6 o'clock end of the specimen there is a light tan pigmented patch 8mm in diameter. The rest of the skin is unremarkable. See macro photos

- A. Section through skin lesion.
- B. Section through mass and 9 o'clock margin.
- C. Section through mass and 3 o'clock margin.
- D. Section from mass to deep margin.
- E. One node bisected.
- F. Four nodes.
- G. One node bisected.
- H. One node bisected.
- J. One node bisected.
- K. Three nodes.

100-0-3
Melanoma, NOS 8720/3
Site: lymph node, groin c27.4
lw 6/10/11

MICROSCOPIC REPORT

"RIGHT GROIN CONTENTS STAPLED UPPER".

The mass described macroscopically is a lymph node extensively replaced by a pleomorphic epithelioid cell tumour consistent with metastatic melanoma. No extra nodal spread is identified. The tumour appears clear of the margin. No evidence of malignancy is seen in a further eight lymph nodes.

The specimen will be reexamined for lymph nodes and a supplementary report issued if further nodes are identified.

SUMMARY

RIGHT GROIN CONTENTS:

- malignant tumour consistent with metastatic melanoma in one of nine lymph nodes. Please see report.

REPORTED BY: Prof.

A Unit of

Printed

Source: NCI Genomic Data Commons file 30ee20a4-86b3-4ad5-8c3b-f8d35f67654a (TCGA-EE-A2GJ.B0FAC3DB-0810-459F-83DA-150B03EEE01F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).